Surgical pathology report (de-identified scan), TCGA case TCGA-W7-A93N, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Garvan Institute of Medical Research, specimen TCGA-W7-A93N-01A (Primary Tumor).

[page 1 of 6]
Cholangiocarcinoma 816013
Site: Common bile duct
C24.0
JW 2/16/14

INTERPRETATION AND DIAGNOSIS:

1) PANCREATIC NECK (EXCISION): NEGATIVE FOR TUMOR.

2) PANCREAS, DUODENUM, BILE DUCT, GALLBLADDER:

SPECIMEN TYPE:

Pancreaticoduodenectomy (Whipple procedure) with cholecystectomy

TUMOR SITE:

Distal common bile duct

HISTOLOGIC TYPE:

Adenocarcinoma

TUMOR SIZE:

1.8 cm

HISTOLOGIC GRADE:

Poorly differentiated

LOCAL EXTENSION:

Pancreas and soft tissues around distal common bile duct and pancreas

EXTENT OF INVASION

PRIMARY TUMOR:

pT3: Tumor invades the pancreas

REGIONAL LYMPH NODES:

pN1: Regional lymph node metastasis

Number examined: 58

Number involved: 2

MARGINS:

Margins uninvolved by invasive carcinoma

PERINEURAL INVASION:

Present

(Continued on next page.)

[page 2 of 6]
LYMPHOVASCULAR INVASION:
Present

ADDITIONAL PATHOLOGIC FINDINGS:
Biliary high grade dysplasia
Common bile duct stricture
Pancreatic intraepithelial neoplasia, grade 2
Chronic cholecystitis

3) BILIARY STENT (REMOVAL): STENT (GROSS DIAGNOSIS).

4) BILE DUCT REMNANT (EXCISION): INFLAMED BILE DUCT WITH REACTIVE
CHANGES. NEGATIVE FOR TUMOR.

NOTE: has seen representative slides to this case and
concurs.

* Electronic signature
=====

Clinical History:
PANCREATIC TUMOR

GROSS DESCRIPTION

(Continued on next page.)

[page 3 of 6]
F

FS: Pancreatic neck: Negative for tumor.

Dictated by:

The specimen is received fresh labeled with the patient's name, and designated 'pancreatic neck margin'. It consists of a single fragment of tan red soft tissue, measuring 2.7 x 1.6 x 0.4 cm. The specimen is submitted in its entirety for FSC diagnosis.

SUMMARY OF SECTIONS:

1 - FSC - 1
1 -TOTAL - 1

(Continued on next page.)

[page 4 of 6]
FS: Whipple specimen: Adenocarcinoma, involving common bile duct and pancreas. Common bile duct, inked uncinata and proximal duodenal margins, negative for tumor. Common bile duct stricture, 1.8 cm.

Dictated by: .

The specimen is received fresh labeled with the patient's name,) and designated 'Whipple specimen'. It consists of a Whipple resection of pancreas, duodenum, and gallbladder. The specimen is oriented by a stitch marking uncinata margin. The pancreas measures 6 x 6 x 2.4 cm. The common bile duct is markedly dilated at a distal portion measuring 0.4 cm in diameter. The length of the common bile duct measures 4.3 cm. Upon opening the common bile duct, stricture is identified measuring 2 x .4 cm in average diameter. Serial sectioning of the pancreas reveals an ill-defined, firm and tan mass lesion surrounding the constricted common bile duct, measuring 1.8 x 1.2 cm. Grossly this lesion is located 1.4 cm from the neck margin, 1.5 cm from the common bile duct margin, and 4 cm from the uncinata margin. The uninvolved pancreatic parenchyma has a tan yellow and lobulated appearance and is grossly unremarkable. The duodenum measures 19 cm in length and 3.2 cm in average diameter. The serosal surface of the duodenum is tan/pink and smooth with minimal amount of attached tan yellow and lobulated fibroadipose tissue and is grossly and remarkable. The duodenum is opened longitudinally to reveal tan and well folded mucosa with no abnormalities identified grossly. The gallbladder measures 10.5 x 4.5 x 1.5 cm. The serosal surface is pink and smooth and is grossly unremarkable. The mucosal surface of the gallbladder is green/brown and is velvety with no abnormalities identified, grossly. No calculi

(Continued on next page.)

[page 5 of 6]
are present. The average thickness of the gallbladder wall is 0.3 cm. Sections taken from the stricture of the common bile duct and the ill defined mass are submitted for frozen section diagnosis. The uncinate margin, common bile duct margin, and the proximal margin of the duodenum is also submitted for FSC diagnosis. The entire peri-common bile duct lesion and the entire peripancreatic soft tissue are submitted. Representative sections of the remaining tissue are submitted. Tissues are harvested for future studies.

SUMMARY OF SECTIONS:

1	- FSC-	= 1
1	- FSC-	- 1
1	- PANM	- 1
2	- P1-2	- 1 EA.
1	- DM	- 1
4	- T1-4	- 1 EA.
1	- AMP	- 1
2	-CBD1-2	- 1 EA.
1	- DUOD	- 1
1	- PST1	- M
1	- PST2	- 2 (ONE POSSIBLE LYMPH NODE)
11	- PST3-13	- M
1	- GB	- 3
3	- FSCT1-3	- 1 EA.
1	- FSC-	- 1
32	-TOTAL	- M

PART #3: BILIARY STENT GROSS ONLY

Resident Pathologist:

Dictated by:

The specimen is received fresh labeled with the patient's name, and designated 'biliary stent'. It consists of a blue and plastic tube measuring 10 cm in length and 0.3 cm in diameter. No attached soft tissue is identified. The specimen is submitted in its entirety for gross exam only. The specimen is placed on permanent save. No sections are submitted.

(Continued on next page.)

[page 6 of 6]
The specimen is received fresh labeled with the patient's name, and designated 'bile duct remnant'. It consists of a pink tan soft tissue fragment with a lumen measuring 1.0 cm in length, and 0.5 cm in diameter. The specimen is serially sectioned to reveal no gross lesions or masses. The specimen is submitted in its entirety as cross sections.

SUMMARY OF SECTIONS:

1 - A - 3
1 - TOTAL - 3

(End of Report)

printed

Source: NCI Genomic Data Commons file 5f43a1b7-6b53-4393-af13-eadcc026ff82 (TCGA-W7-A93N.11CECB43-24AE-4F25-B7C6-01783A148138.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).